Somatic mutation profile of cancer-model specimen HCM-SANG-0308-C15-85A (3D Organoid; aliquot HCM-SANG-0308-C15-85A-01D-A78M-36), derived from the primary tumor of HCMI case HCM-SANG-0308-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0308-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1bcc5a07-cc89-4444-b324-c87383781e62.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0308-C15-10A (Blood Derived Normal), aliquot HCM-SANG-0308-C15-10A-01D-A78M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0fcb2e77-ba16-47ee-b7e7-fe27f96f963a

The open-access MAF lists 277 somatic variants for this specimen: 182 protein-altering or splice-affecting, 63 silent, 32 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 161, Silent 63, Intron 10, RNA 8, Nonsense Mutation 6, Frame Shift Ins 5, Frame Shift Del 4, 3'UTR 4, 5'Flank 4, 5'UTR 4, Splice Region 3, Splice Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SPRED1 | c.52C>T p.R18* | Nonsense Mutation (SNP) | VAF 111/180 reads (62%) | catalogued as rs750777752, CM097989, COSV54438940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.764_766del p.I255del | In Frame Del (DEL) | VAF 153/170 reads (90%) | hotspot (GDC flag); catalogued as rs1064794309; called by pindel, varscan2
- AATK | c.2158G>A p.E720K (on ENST00000326724 / NM_001080395.3; = p.E617K on NM_004920.2) | Missense Mutation (SNP) | VAF 41/102 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.07); catalogued as rs1031641443; called by muse, mutect2, varscan2
- ACSBG2 | c.291G>T p.L97F | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV99397596; called by muse, mutect2, varscan2
- ADAD2 | c.494C>T p.T165M (on ENST00000315906 / NM_001145400.2; = p.T237M on NM_139174.4) | Missense Mutation (SNP) | VAF 197/433 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as rs541963401, COSV99235212; called by muse, mutect2, varscan2
- ADAM17 | c.1531G>A p.G511S | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.641); catalogued as rs554069834; ClinVar: uncertain significance; called by muse, mutect2
- ADAMTS16 | c.3535T>G p.F1179V | Missense Mutation (SNP) | VAF 47/88 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV56980550; called by muse, mutect2, varscan2
- ANKRD13B | c.1640G>A p.R547H | Missense Mutation (SNP) | VAF 239/651 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.469); catalogued as COSV61472162; called by muse, mutect2, varscan2
- ANXA11 | c.1342G>C p.G448R | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99626763; called by muse, mutect2
- APC | c.4537G>T p.E1513* | Nonsense Mutation (SNP) | VAF 74/74 reads (100%) | catalogued as COSV57348031; called by muse, mutect2, varscan2
- AQP10 | c.572C>T p.P191L | Missense Mutation (SNP) | VAF 347/348 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1432561293; called by muse, mutect2, varscan2
- AR | c.2202G>C p.Q734H | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM983649, COSV65964532; called by muse, mutect2, varscan2
- ATP10A | c.209C>T p.T70M | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs768569410, COSV63513261; called by muse, mutect2, varscan2
- BCL11B | c.2290C>T p.L764F (on ENST00000357195 / NM_001282237.2; = p.L693F on NM_022898.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 92/491 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.379); catalogued as rs1469850649; called by muse, mutect2, varscan2
- C1QL2 | c.52del p.R18Efs*8 | Frame Shift Del (DEL) | VAF 93/251 reads (37%) | catalogued as COSV55607575; called by mutect2, pindel, varscan2
- CAMKV | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 207/209 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1220869354, COSV56555172; called by muse, mutect2, varscan2
- CCL4 | c.214C>G p.Q72E | Missense Mutation (SNP) | VAF 54/408 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.01); catalogued as rs772985242; called by muse, varscan2
- CDC14C | c.335C>T p.T112M (on ENST00000428251; = p.T5M on NM_152627.3) | Missense Mutation (SNP) | VAF 67/119 reads (56%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.012); catalogued as rs766356437; called by muse, mutect2, varscan2
- CDH3 | c.1279A>G p.I427V | Missense Mutation (SNP) | VAF 102/731 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs201586086; called by muse, mutect2, varscan2
- CEP131 | c.2248C>T p.R750C (on ENST00000269392 / NM_001319228.2; = p.R747C on NM_014984.4) | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.897); catalogued as rs752744561, COSV53950755; called by muse, mutect2, varscan2
- CHL1 | c.3080T>C p.L1027P (on ENST00000397491 / NM_001253387.1; = p.L1043P on NM_006614.4) | Missense Mutation (SNP) | VAF 45/45 reads (100%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56594798, COSV56602147, COSV56609114; called by muse, mutect2, varscan2
- CHRNB3 | c.649G>A p.V217M | Missense Mutation (SNP) | VAF 22/160 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs760859517; called by muse, mutect2, varscan2
- COL4A5 | c.4184C>A p.P1395H | Missense Mutation (SNP) | VAF 122/122 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.417); catalogued as rs755087742, CD129406; called by muse, mutect2, varscan2
- CTIF | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 13/195 reads (7%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as rs764007021; called by muse, mutect2
- CYP2A6 | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.841); catalogued as COSV56534878; called by muse, mutect2, varscan2
- DMD | c.7872G>T p.K2624N | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58910277; called by muse, mutect2, varscan2
- DNAH1 | c.7076G>A p.R2359H | Missense Mutation (SNP) | VAF 279/287 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs748543554, COSV70233697; called by muse, mutect2, varscan2
- DNAH17 | c.5770C>T p.R1924W | Missense Mutation (SNP) | VAF 46/113 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768967388, COSV67752677; called by muse, mutect2, varscan2
- FAM189A1 | c.1472T>C p.V491A | Missense Mutation (SNP) | VAF 47/234 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.112); catalogued as COSV99723357; called by muse, varscan2
- FNDC3A | c.1907T>C p.L636S (on ENST00000492622 / NM_001079673.2; = p.L580S on NM_014923.5) | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1335407907; called by muse, mutect2, varscan2
- GALNT3 | c.1883T>A p.I628K | Missense Mutation (SNP) | VAF 63/112 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.07); catalogued as COSV101204936; called by muse, mutect2, varscan2
- GAS2L1 | c.1664C>G p.A555G | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99329705; called by muse, mutect2, varscan2
- GPR22 | c.1058T>C p.L353S | Missense Mutation (SNP) | VAF 45/78 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs918571293, COSV51741846; called by muse, mutect2, varscan2
- GTF2IRD2 | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 47/78 reads (60%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs1554416233; called by mutect2, varscan2
- IFI16 | c.12del p.K4Nfs*8 | Frame Shift Del (DEL) | VAF 6/10 reads (60%) | catalogued as rs1272199515; called by mutect2, varscan2
- ITGB7 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 68/303 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs1422866769; called by muse, mutect2, varscan2
- KNDC1 | c.4904G>A p.R1635H | Missense Mutation (SNP) | VAF 141/319 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as rs1298959439, COSV100466644; called by muse, mutect2, varscan2
- LHFPL6 | c.404G>A p.G135D | Missense Mutation (SNP) | VAF 47/149 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65443936; called by muse, mutect2, varscan2
- LMTK3 | c.4131dup p.E1378Rfs*162 | Frame Shift Ins (INS) | VAF 12/16 reads (75%) | catalogued as rs758225154; called by mutect2, varscan2
- MAGEC2 | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 32/75 reads (43%) | SIFT tolerated (0.65); PolyPhen benign (0.01); catalogued as rs765614781; called by muse, mutect2, varscan2
- MAP3K14 | c.2557G>A p.D853N | Missense Mutation (SNP) | VAF 114/214 reads (53%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.651); catalogued as rs766785713; called by muse, varscan2
- MAP3K14 | c.2459C>T p.S820L | Missense Mutation (SNP) | VAF 116/237 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs372258853; called by muse, varscan2
- MAPK13 | c.887G>A p.R296H | Missense Mutation (SNP) | VAF 67/121 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370476051, COSV52983472; called by muse, mutect2, varscan2
- MCF2L2 | c.2662C>G p.P888A | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.219); catalogued as rs779255516; called by muse, mutect2
- MYRF | c.2035G>A p.V679I (on ENST00000278836 / NM_001127392.3; = p.V670I on NM_013279.4) | Missense Mutation (SNP) | VAF 190/242 reads (79%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs775821256, COSV53886269; called by muse, mutect2, varscan2
- NDUFAF6 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT tolerated (0.52); PolyPhen benign (0.015); catalogued as rs1392002240; called by muse, varscan2
- NME8 | c.1210A>G p.R404G | Missense Mutation (SNP) | VAF 94/248 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as COSV52254619, COSV99553357, COSV99553951; called by muse, mutect2, varscan2
- NR1H2 | c.65G>A p.G22D | Missense Mutation (SNP) | VAF 28/38 reads (74%) | SIFT tolerated (0.36); PolyPhen benign (0.021); catalogued as rs372060949; called by muse, mutect2, varscan2
- NRK | c.1877C>A p.T626K | Missense Mutation (SNP) | VAF 35/84 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs1160019887, COSV54596461; called by muse, mutect2, varscan2
- NUP155 | c.2260G>A p.G754R (on ENST00000231498 / NM_153485.3; = p.G695R on NM_004298.4) | Missense Mutation (SNP) | VAF 88/88 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs145147317; called by muse, mutect2, varscan2
- NXPE4 | c.115T>G p.L39V | Missense Mutation (SNP) | VAF 73/92 reads (79%) | SIFT tolerated (0.42); PolyPhen benign (0.218); catalogued as COSV64944553, COSV64944639; called by muse, mutect2, varscan2
- OR4D2 | c.562G>T p.A188S | Missense Mutation (SNP) | VAF 364/843 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV73459712; called by muse, mutect2, varscan2
- P2RY4 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 108/108 reads (100%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); catalogued as rs201727833, COSV65736326; called by muse, mutect2, varscan2
- PAQR4 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 254/582 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as rs113627401; called by muse, mutect2, varscan2
- PARP4 | c.3994C>T p.R1332C | Missense Mutation (SNP) | VAF 124/175 reads (71%) | SIFT tolerated (0.16); PolyPhen benign (0.019); catalogued as rs200648886; called by muse, mutect2, varscan2
- PCDH17 | c.3074T>C p.L1025P | Missense Mutation (SNP) | VAF 39/113 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs1198267761; called by muse, mutect2, varscan2
- PCDHA11 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 37/416 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs781950776, COSV56559987; called by muse, mutect2
- PCDHGA12 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 19/487 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as COSV52753880; called by muse, mutect2
- PEAK1 | c.3871C>T p.R1291* | Nonsense Mutation (SNP) | VAF 74/331 reads (22%) | catalogued as COSV100432636; called by muse, mutect2, varscan2
- PLCH2 | c.4021C>T p.R1341C | Missense Mutation (SNP) | VAF 68/301 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.94); catalogued as rs765406097; called by muse, mutect2, varscan2
- PNPLA3 | c.1210G>A p.A404T | Missense Mutation (SNP) | VAF 33/190 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756325486; called by muse, mutect2, varscan2
- PPP1R3A | c.368T>G p.L123R | Missense Mutation (SNP) | VAF 118/361 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52894224; called by muse, mutect2, varscan2
- PTPRT | c.653A>C p.K218T | Missense Mutation (SNP) | VAF 123/317 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as COSV61972289, COSV99049504; called by muse, mutect2, varscan2
- SAGE1 | c.1466G>A p.R489H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.329); catalogued as rs782681413, COSV61016346; called by muse, mutect2, varscan2
- SEPTIN4 | c.97G>A p.E33K | Missense Mutation (SNP) | VAF 201/586 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.129); catalogued as COSV57897071; called by muse, mutect2, varscan2
- SLC39A13 | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 97/495 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as rs369854018; called by muse, mutect2, varscan2
- SLC47A2 | c.1109C>T p.S370L | Missense Mutation (SNP) | VAF 98/98 reads (100%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs1450879097; called by muse, mutect2, varscan2
- SLC6A12 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 85/195 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs759619929, COSV100675120; called by muse, mutect2, varscan2
- SLC9C2 | c.2425C>T p.R809W | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1351284968, COSV100876564, COSV100877048; called by muse, mutect2
- SPATA13 | c.191A>G p.K64R | Missense Mutation (SNP) | VAF 14/186 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV101173185; called by muse, mutect2
- STAT1 | c.1804C>T p.R602W | Missense Mutation (SNP) | VAF 266/522 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1209841496; called by muse, mutect2, varscan2
- SULF1 | c.1929G>T p.K643N | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52680523; called by muse, mutect2, varscan2
- TTC7A | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 22/357 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV55414519; called by muse, mutect2
- USP42 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.558); catalogued as rs374814529, COSV60357608; called by muse, mutect2, varscan2
- VCAN | c.6783A>C p.E2261D | Missense Mutation (SNP) | VAF 64/64 reads (100%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as COSV99426683; called by muse, mutect2, varscan2
- WASHC2A | c.1115A>T p.D372V | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as rs1554883603; called by muse, mutect2, varscan2
- WDR24 | c.1940C>T p.S647L (on ENST00000248142; = p.S517L on NM_032259.4) | Missense Mutation (SNP) | VAF 166/352 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.146); catalogued as COSV50197747; called by muse, mutect2, varscan2
- XPNPEP2 | c.797C>T p.T266M | Missense Mutation (SNP) | VAF 89/89 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs764833021; called by muse, mutect2, varscan2
- XPO4 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 21/66 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.421); catalogued as rs769263016; called by muse, mutect2, varscan2
- ZFHX4 | c.6716G>A p.R2239K | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.98); catalogued as COSV50552210; called by muse, mutect2, varscan2
- ZNF347 | c.458A>G p.K153R | Missense Mutation (SNP) | VAF 43/70 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.152); catalogued as rs1434443476; called by muse, mutect2, varscan2
- ZNF750 | c.1528G>A p.G510R | Missense Mutation (SNP) | VAF 152/297 reads (51%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs775795396; called by muse, mutect2, varscan2
- ZNF837 | c.427C>T p.P143S | Missense Mutation (SNP) | VAF 76/227 reads (33%) | SIFT tolerated (0.32); PolyPhen benign (0.099); catalogued as rs1201720482; called by muse, mutect2, varscan2
- ADAMTS3 | c.1925A>G p.K642R | Missense Mutation (SNP) | VAF 31/32 reads (97%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADGRV1 | c.2950G>A p.G984R | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AL133268.3 | n.78+5C>A | Splice Region (SNP) | VAF 52/126 reads (41%) | called by muse, mutect2, varscan2
- ARHGEF28 | c.3690T>A p.C1230* | Nonsense Mutation (SNP) | VAF 37/125 reads (30%) | called by muse, mutect2, varscan2
- ASB15 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 65/117 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASPM | c.8829G>T p.W2943C | Missense Mutation (SNP) | VAF 61/88 reads (69%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- ATP6V1C1 | c.846G>C p.W282C | Missense Mutation (SNP) | VAF 51/142 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8B4 | c.3287T>C p.L1096P | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BICD2 | c.2455C>T p.P819S | Missense Mutation (SNP) | VAF 56/489 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- C16orf96 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 58/130 reads (45%) | SIFT tolerated (0.36); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C6orf163 | c.289G>C p.A97P | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.241); called by muse, mutect2
- C8B | c.1571T>G p.I524S | Missense Mutation (SNP) | VAF 16/338 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); called by muse, mutect2
- CCDC168 | c.13393C>A p.Q4465K | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT tolerated (0.45); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CCNB3 | c.590A>G p.Q197R | Missense Mutation (SNP) | VAF 63/66 reads (95%) | SIFT tolerated (0.36); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CDK11A | c.366del p.K123Nfs*37 (on ENST00000378633 / NM_001313896.2; = p.K133Nfs*37 on NM_024011.4) | Frame Shift Del (DEL) | VAF 214/299 reads (72%) | called by mutect2, pindel, varscan2
- CENPBD1 | c.253G>C p.A85P | Missense Mutation (SNP) | VAF 110/208 reads (53%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- CENPC | c.455T>G p.F152C | Missense Mutation (SNP) | VAF 50/51 reads (98%) | SIFT tolerated (0.05); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CFAP46 | c.6511C>T p.L2171F | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2
- CROT | c.1446G>C p.K482N | Missense Mutation (SNP) | VAF 16/103 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CTSO | c.428C>A p.S143Y | Missense Mutation (SNP) | VAF 69/71 reads (97%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCDC1 | c.356C>A p.S119* | Nonsense Mutation (SNP) | VAF 157/202 reads (78%) | called by muse, mutect2, varscan2
- DIDO1 | c.2833G>C p.D945H | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- DIP2B | c.2484del p.I828Mfs*8 | Frame Shift Del (DEL) | VAF 78/142 reads (55%) | called by mutect2, pindel, varscan2
- DMRTB1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- DNAH10 | c.9617T>G p.L3206R (on ENST00000409039; = p.L3145R on NM_207437.3) | Missense Mutation (SNP) | VAF 133/156 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNER | c.680A>G p.K227R | Missense Mutation (SNP) | VAF 86/198 reads (43%) | SIFT tolerated (0.16); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EN1 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 29/258 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- EPHA6 | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- EYS | c.38T>G p.V13G | Missense Mutation (SNP) | VAF 110/199 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- FAM83H | c.3332C>A p.A1111D | Missense Mutation (SNP) | VAF 82/636 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- FAT1 | c.12571G>T p.G4191W | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FAT3 | c.1171C>G p.P391A | Missense Mutation (SNP) | VAF 97/145 reads (67%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNDC1 | c.3769G>A p.V1257I | Missense Mutation (SNP) | VAF 104/222 reads (47%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GABRA6 | c.443T>A p.M148K | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GAS6 | c.1107C>A p.S369R | Missense Mutation (SNP) | VAF 18/362 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); called by muse, mutect2
- GSPT2 | c.1352A>G p.E451G | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- GTF2IRD2B | c.2567C>T p.T856M | Missense Mutation (SNP) | VAF 12/125 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by mutect2, varscan2
- HCN4 | c.3514G>T p.A1172S | Missense Mutation (SNP) | VAF 120/372 reads (32%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- IGSF10 | c.2444A>T p.N815I | Missense Mutation (SNP) | VAF 293/303 reads (97%) | SIFT tolerated (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ITGA3 | c.2138G>A p.R713K | Missense Mutation (SNP) | VAF 5/132 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- ITGAV | c.698A>C p.K233T | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KIAA1109 | c.14680dup p.S4894Kfs*7 | Frame Shift Ins (INS) | VAF 42/61 reads (69%) | called by mutect2, pindel, varscan2
- LGR5 | c.1071A>G p.L357= | Splice Region (SNP) | VAF 21/48 reads (44%) | called by muse, mutect2, varscan2
- LOXHD1 | c.5759C>A p.A1920D (on ENST00000642948; = p.A1858D on NM_144612.7) | Missense Mutation (SNP) | VAF 192/192 reads (100%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- LRP1 | c.4463G>T p.G1488V | Missense Mutation (SNP) | VAF 73/333 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRP1B | c.766T>C p.S256P | Missense Mutation (SNP) | VAF 33/74 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MCAM | c.249C>A p.S83R | Missense Mutation (SNP) | VAF 356/459 reads (78%) | SIFT tolerated (0.28); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MED24 | c.1604A>C p.E535A | Missense Mutation (SNP) | VAF 186/404 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- MYO1A | c.1771C>G p.P591A | Missense Mutation (SNP) | VAF 91/431 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NEFH | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 50/260 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- NKAIN2 | c.389A>G p.D130G | Missense Mutation (SNP) | VAF 147/149 reads (99%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.632); called by muse, mutect2, varscan2
- NOC3L | c.593T>G p.L198R | Missense Mutation (SNP) | VAF 39/85 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); called by muse, mutect2
- NPC1L1 | c.2637G>A p.K879= | Splice Region (SNP) | VAF 14/373 reads (4%) | called by muse, mutect2
- NT5C2 | c.964C>A p.Q322K | Missense Mutation (SNP) | VAF 55/235 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OLFM4 | c.401T>G p.L134R | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- OR2W3 | c.269A>C p.K90T | Missense Mutation (SNP) | VAF 275/275 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR52E8 | c.691T>G p.F231V | Missense Mutation (SNP) | VAF 74/74 reads (100%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- OR5D18 | c.242A>T p.K81M | Missense Mutation (SNP) | VAF 90/111 reads (81%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); called by muse, mutect2, varscan2
- OR5T3 | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 22/133 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- PAK5 | c.2131C>T p.P711S | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2
- PCDH15 | c.2663A>G p.Q888R | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT tolerated (0.3); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PCDH15 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); called by muse, varscan2
- PCDH7 | c.1343C>T p.S448F | Missense Mutation (SNP) | VAF 37/177 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- PDZRN3 | c.515C>T p.A172V | Missense Mutation (SNP) | VAF 85/88 reads (97%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- PNPLA4 | c.587G>C p.G196A | Missense Mutation (SNP) | VAF 12/153 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2
- POM121L12 | c.127A>T p.T43S | Missense Mutation (SNP) | VAF 134/374 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPP2R2D | c.907G>A p.G303R | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRAMEF27 | c.557dup p.L187Afs*119 | Frame Shift Ins (INS) | VAF 10/56 reads (18%) | called by mutect2, varscan2
- PRDM12 | c.80T>G p.V27G | Missense Mutation (SNP) | VAF 66/544 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PRRG3 | c.484A>T p.S162C | Missense Mutation (SNP) | VAF 34/34 reads (100%) | SIFT deleterious (0.02); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- PTPRT | c.2007G>T p.K669N | Missense Mutation (SNP) | VAF 378/698 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.238); called by muse, mutect2, varscan2
- PZP | c.124G>C p.A42P | Missense Mutation (SNP) | VAF 34/194 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RGPD4 | c.1827A>C p.K609N | Missense Mutation (SNP) | VAF 37/102 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- RPS6KA6 | c.323A>G p.K108R | Missense Mutation (SNP) | VAF 27/27 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RRS1 | c.316C>T p.P106S | Missense Mutation (SNP) | VAF 179/352 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGK3 | c.97-2A>G p.X33_splice | Splice Site (SNP) | VAF 27/45 reads (60%) | called by muse, mutect2, varscan2
- SLC29A1 | c.46C>T p.L16F | Missense Mutation (SNP) | VAF 34/489 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.21); called by muse, mutect2
- SLC41A1 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 15/332 reads (5%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.675); called by muse, mutect2
- SLITRK2 | c.985G>T p.V329L | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- SP9 | c.432dup p.L145Afs*268 | Frame Shift Ins (INS) | VAF 71/163 reads (44%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.1979A>C p.K660T | Missense Mutation (SNP) | VAF 150/761 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPIN3 | c.127T>A p.S43T | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT tolerated (0.16); PolyPhen benign (0.009); called by muse, mutect2
- STYXL2 | c.424T>A p.F142I | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SVEP1 | c.278G>T p.S93I | Missense Mutation (SNP) | VAF 637/647 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TENM1 | c.536-1G>C p.X179_splice | Splice Site (SNP) | VAF 10/62 reads (16%) | called by muse, mutect2, varscan2
- TET3 | c.4306G>A p.G1436R | Missense Mutation (SNP) | VAF 7/98 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.887); called by muse, mutect2
- THNSL2 | c.379T>G p.F127V | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMIGD3 | c.309dup p.K104Qfs*10 (on ENST00000369717 / NM_001081976.2; = p.K185Qfs*10 on NM_020683.7) | Frame Shift Ins (INS) | VAF 32/161 reads (20%) | called by mutect2, pindel, varscan2
- TRNP1 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0); called by muse, mutect2, varscan2
- TUBGCP5 | c.1988A>C p.K663T | Missense Mutation (SNP) | VAF 36/59 reads (61%) | SIFT tolerated (0.35); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- UBE4B | c.435G>T p.K145N | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2
- WDR97 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 281/658 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBBX | c.1347T>A p.D449E | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZEB2 | c.2162C>A p.P721H | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- ZFHX4 | c.10084G>A p.D3362N | Missense Mutation (SNP) | VAF 30/220 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF347 | c.459A>T p.K153N | Missense Mutation (SNP) | VAF 44/72 reads (61%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF804A | c.3015A>T p.L1005F | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZSCAN5A | c.1419T>A p.C473* | Nonsense Mutation (SNP) | VAF 55/88 reads (63%) | called by muse, mutect2, varscan2
- ZSWIM3 | c.1960G>T p.G654C | Missense Mutation (SNP) | VAF 155/414 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ABCA3 | c.897C>A p.L299= | Silent (SNP) | VAF 45/266 reads (17%) | catalogued as rs1186630019; called by muse, mutect2, varscan2
- ADAMTS12 | c.2688G>C p.A896= | Silent (SNP) | VAF 61/214 reads (29%) | catalogued as rs201796524, COSV61275738; called by muse, mutect2, varscan2
- ANKRD33B | c.282C>T p.C94= | Silent (SNP) | VAF 125/265 reads (47%) | catalogued as rs62337439, COSV99686314; called by muse, mutect2, varscan2
- ATP13A1 | c.2193C>T p.A731= | Silent (SNP) | VAF 73/224 reads (33%) | catalogued as rs767748918; called by muse, mutect2, varscan2
- AURKB | c.291G>A p.K97= | Silent (SNP) | VAF 41/131 reads (31%) | called by muse, mutect2, varscan2
- BVES | c.1041A>G p.E347= | Silent (SNP) | VAF 19/42 reads (45%) | called by muse, mutect2, varscan2
- CABP5 | c.315C>T p.I105= | Silent (SNP) | VAF 98/155 reads (63%) | catalogued as rs372942092; called by muse, mutect2, varscan2
- CCDC50 | c.789A>G p.R263= | Silent (SNP) | VAF 92/95 reads (97%) | called by muse, mutect2, varscan2
- CD1B | c.864C>T p.G288= | Silent (SNP) | VAF 26/110 reads (24%) | called by mutect2, varscan2
- CDH5 | c.1011C>T p.V337= | Silent (SNP) | VAF 124/259 reads (48%) | catalogued as rs925139568, COSV58517784; called by muse, mutect2, varscan2
- CHRNB4 | c.852C>T p.I284= | Silent (SNP) | VAF 231/363 reads (64%) | catalogued as rs377658350; called by muse, mutect2, varscan2
- CLCN1 | c.2592G>A p.E864= | Silent (SNP) | VAF 17/186 reads (9%) | called by muse, mutect2
- CNBD1 | c.498A>G p.K166= | Silent (SNP) | VAF 6/15 reads (40%) | called by muse, mutect2, varscan2
- CNTN3 | c.708T>C p.T236= | Silent (SNP) | VAF 57/60 reads (95%) | catalogued as COSV55161790; called by muse, mutect2, varscan2
- DGKD | c.2688C>T p.I896= (on ENST00000264057 / NM_152879.3; = p.I852= on NM_003648.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 40/98 reads (41%) | catalogued as rs1480812455, COSV51040736, COSV99897644; called by muse, mutect2, varscan2
- FCN2 | c.180G>T p.G60= | Silent (SNP) | VAF 163/403 reads (40%) | called by muse, mutect2, varscan2
- FLT4 | c.3970C>A p.R1324= | Silent (SNP) | VAF 174/175 reads (99%) | catalogued as COSV56127231; called by muse, mutect2, varscan2
- FMN1 | c.1104C>T p.A368= | Silent (SNP) | VAF 111/297 reads (37%) | catalogued as rs1322997884; called by muse, mutect2, varscan2
- FMO3 | c.684T>G p.G228= | Silent (SNP) | VAF 162/163 reads (99%) | called by muse, mutect2, varscan2
- GSX1 | c.729C>T p.D243= | Silent (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2
- HOXB9 | c.384G>A p.L128= | Silent (SNP) | VAF 148/343 reads (43%) | called by muse, mutect2, varscan2
- IRGQ | c.1218C>T p.G406= | Silent (SNP) | VAF 191/291 reads (66%) | called by muse, mutect2, varscan2
- IRS2 | c.1821C>A p.G607= | Silent (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- KCNN3 | c.1512C>T p.D504= (on ENST00000618040 / NM_001204087.1; = p.D489= on NM_002249.6) | Silent (SNP) | VAF 18/386 reads (5%) | catalogued as rs576034957; called by muse, mutect2
- KCP | c.4305C>T p.P1435= (on ENST00000620378; = p.P1559= on NM_001366122.1) | Silent (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- KHK | c.462C>T p.D154= | Silent (SNP) | VAF 370/658 reads (56%) | catalogued as rs768290702; called by muse, mutect2, varscan2
- KRT72 | c.834G>A p.T278= | Silent (SNP) | VAF 26/101 reads (26%) | catalogued as rs201887205; called by muse, mutect2, varscan2
- MACC1 | c.351T>C p.G117= | Silent (SNP) | VAF 11/76 reads (14%) | called by muse, mutect2, varscan2
- MAP3K14 | c.1587C>T p.H529= | Silent (SNP) | VAF 267/531 reads (50%) | catalogued as rs562409633; ClinVar: likely benign; called by muse, mutect2, varscan2
- MAPK15 | c.1617G>A p.L539= | Silent (SNP) | VAF 58/141 reads (41%) | called by mutect2, varscan2
- MMP28 | c.648G>A p.A216= | Silent (SNP) | VAF 37/244 reads (15%) | catalogued as rs1448338034; called by muse, mutect2, varscan2
- NCAM2 | c.972G>A p.A324= | Silent (SNP) | VAF 12/41 reads (29%) | catalogued as rs192323183; called by muse, varscan2
- NKX1-2 | c.378G>A p.A126= | Silent (SNP) | VAF 82/226 reads (36%) | called by muse, mutect2, varscan2
- NWD2 | c.3196C>T p.L1066= | Silent (SNP) | VAF 8/216 reads (4%) | called by muse, mutect2
- PCSK2 | c.1332C>T p.Y444= | Silent (SNP) | VAF 116/193 reads (60%) | catalogued as rs765711439; called by muse, mutect2, varscan2
- PHF21A | c.1194G>A p.P398= (on ENST00000418153 / NM_001101802.3; = p.P399= on NM_016621.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 95/151 reads (63%) | catalogued as rs768776752, COSV99138729; called by muse, mutect2, varscan2
- PIANP | c.435A>C p.S145= | Silent (SNP) | VAF 18/524 reads (3%) | called by muse, mutect2
- PNPLA4 | c.588G>T p.G196= | Silent (SNP) | VAF 11/151 reads (7%) | catalogued as COSV66853876; called by muse, mutect2
- PTPRT | c.1236C>T p.Y412= | Silent (SNP) | VAF 244/676 reads (36%) | catalogued as rs376152261, COSV62000894; called by muse, mutect2, varscan2
- RRAS | c.556C>T p.L186= | Silent (SNP) | VAF 27/64 reads (42%) | called by muse, mutect2, varscan2
- RTN1 | c.942A>T p.T314= | Silent (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- RTN4IP1 | c.966C>T p.V322= | Silent (SNP) | VAF 93/93 reads (100%) | called by muse, mutect2, varscan2
- RYR3 | c.1119T>G p.T373= | Silent (SNP) | VAF 38/54 reads (70%) | catalogued as COSV101212027, COSV101215037, COSV66780594; called by muse, mutect2, varscan2
- SACS | c.9559T>C p.L3187= | Silent (SNP) | VAF 15/35 reads (43%) | called by muse, mutect2, varscan2
- SDC1 | c.444C>T p.P148= | Silent (SNP) | VAF 47/188 reads (25%) | catalogued as rs756420300, COSV99587229; called by muse, mutect2, varscan2
- SERPINB13 | c.108T>A p.T36= | Silent (SNP) | VAF 32/150 reads (21%) | called by muse, mutect2, varscan2
- SHISA7 | c.1482C>T p.A494= | Silent (SNP) | VAF 140/213 reads (66%) | called by muse, mutect2, varscan2
- SPI1 | c.12G>A p.A4= | Silent (SNP) | VAF 181/237 reads (76%) | catalogued as COSV57043918; called by muse, mutect2, varscan2
- SPTBN5 | c.8076G>A p.Q2692= | Silent (SNP) | VAF 13/167 reads (8%) | called by muse, mutect2
- SYNPO2L | c.267C>T p.D89= | Silent (SNP) | VAF 24/73 reads (33%) | catalogued as rs1335238106, COSV65737299; called by muse, mutect2, varscan2
- TBX21 | c.1308C>T p.P436= | Silent (SNP) | VAF 77/416 reads (19%) | catalogued as rs748050753; called by muse, mutect2, varscan2
- TMEM132D | c.1380C>T p.D460= | Silent (SNP) | VAF 59/281 reads (21%) | catalogued as rs12815188; called by muse, mutect2, varscan2
- TRIM71 | c.1788C>T p.F596= | Silent (SNP) | VAF 176/181 reads (97%) | catalogued as rs972142499; called by muse, mutect2, varscan2
- TRIP10 | c.1425C>T p.V475= (on ENST00000313244 / NM_001288962.2; = p.V419= on NM_004240.4) | Silent (SNP) | VAF 44/134 reads (33%) | called by muse, mutect2, varscan2
- TSHZ1 | c.1324C>T p.L442= (on ENST00000580243 / NM_001308210.2; = p.L397= on NM_005786.6) | Silent (SNP) | VAF 110/240 reads (46%) | called by muse, mutect2, varscan2
- TTN | c.81078T>A p.T27026= (on ENST00000591111; = p.T19602= on NM_003319.4) | Silent (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.11836T>C p.L3946= (on ENST00000591111; = p.L3900= on NM_003319.4) | Silent (SNP) | VAF 21/44 reads (48%) | catalogued as COSV100624004; called by muse, mutect2, varscan2
- TUBB4A | c.504C>T p.S168= | Silent (SNP) | VAF 129/427 reads (30%) | catalogued as rs143415955; called by muse, mutect2, varscan2
- WDR81 | c.2493C>T p.P831= | Silent (SNP) | VAF 187/196 reads (95%) | catalogued as rs1327576809, COSV58482157; called by muse, mutect2, varscan2
- ZC3H12C | c.2148C>T p.G716= | Silent (SNP) | VAF 34/184 reads (18%) | catalogued as rs1451418946; called by muse, mutect2, varscan2
- ZNF347 | c.2511G>A p.Q837= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as COSV61970749; called by mutect2, varscan2
- ZNF648 | c.837C>T p.Y279= | Silent (SNP) | VAF 237/244 reads (97%) | catalogued as rs767179538; called by muse, mutect2, varscan2
- ZNF689 | c.744G>A p.L248= | Silent (SNP) | VAF 18/65 reads (28%) | called by muse, mutect2, varscan2
- AC079154.1 | n.1021A>C | RNA (SNP) | VAF 27/75 reads (36%) | called by muse, mutect2, varscan2
- AC103993.1 | n.73T>C | RNA (SNP) | VAF 84/175 reads (48%) | catalogued as rs1173503107; called by muse, mutect2, varscan2
- AC116655.1 | n.457C>T | RNA (SNP) | VAF 85/89 reads (96%) | called by muse, mutect2, varscan2
- AL109984.1 | chr20:52097106 G>T | 3'Flank (SNP) | VAF 13/207 reads (6%) | called by muse, mutect2
- AL132655.6 | chr20:58840715 C>A | 5'Flank (SNP) | VAF 137/456 reads (30%) | called by muse, mutect2, varscan2
- ATP7B | c.*14G>T | 3'UTR (SNP) | VAF 90/407 reads (22%) | called by muse, mutect2, varscan2
- C14orf177 | n.625G>T | RNA (SNP) | VAF 49/50 reads (98%) | called by muse, mutect2
- COCH | c.-35C>T | 5'UTR (SNP) | VAF 82/355 reads (23%) | called by muse, mutect2, varscan2
- COL4A2 | c.1340-499G>A | Intron (SNP) | VAF 175/618 reads (28%) | catalogued as rs751620217, COSV64626158; called by muse, mutect2, varscan2
- CRMP1 | chr4:5892957 G>A | 5'Flank (SNP) | VAF 12/22 reads (55%) | called by muse, mutect2, varscan2
- DEPDC5 | c.3186-58G>A | Intron (SNP) | VAF 53/123 reads (43%) | catalogued as rs566038673; called by muse, mutect2, varscan2
- DPPA3P2 | n.661T>A | RNA (SNP) | VAF 52/175 reads (30%) | called by muse, mutect2, varscan2
- FAM122C | c.189+6714C>G | Intron (SNP) | VAF 121/121 reads (100%) | called by muse, varscan2
- FZD5 | c.*7G>T | 3'UTR (SNP) | VAF 30/53 reads (57%) | called by muse, mutect2, varscan2
- GBX2 | c.523+258C>T | Intron (SNP) | VAF 107/262 reads (41%) | catalogued as rs1483909606; called by muse, mutect2, varscan2
- HTR5A | c.-471C>T | 5'UTR (SNP) | VAF 44/103 reads (43%) | called by muse, varscan2
- LITAF | c.*1301G>A | 3'UTR (SNP) | VAF 14/52 reads (27%) | catalogued as rs1243508840; called by muse, mutect2
- MKRN9P | n.495A>G | RNA (SNP) | VAF 47/253 reads (19%) | called by muse, mutect2, varscan2
- MYPN | c.*1236C>T | 3'UTR (SNP) | VAF 48/100 reads (48%) | called by muse, mutect2, varscan2
- PPFIA2 | c.-40C>G | 5'UTR (SNP) | VAF 11/64 reads (17%) | called by muse, mutect2, varscan2
- PYGO1 | c.49+25G>T | Intron (SNP) | VAF 49/89 reads (55%) | called by muse, mutect2, varscan2
- RIPOR2 | c.-106C>T | 5'UTR (SNP) | VAF 88/88 reads (100%) | catalogued as rs1474083174; called by muse, mutect2, varscan2
- SCOC-AS1 | n.6568A>C | RNA (SNP) | VAF 88/90 reads (98%) | called by muse, mutect2, varscan2
- SLC17A9 | c.1147+27A>T | Intron (SNP) | VAF 20/310 reads (6%) | called by muse, mutect2
- SYCE1 | chr10:133568294 G>A | 5'Flank (SNP) | VAF 78/193 reads (40%) | catalogued as rs1487737070; called by muse, mutect2, varscan2
- TLCD2 | chr17:1713703 C>A | 5'Flank (SNP) | VAF 7/23 reads (30%) | called by muse, mutect2, varscan2
- TMEM144 | c.109+49A>T | Intron (SNP) | VAF 9/46 reads (20%) | called by muse, mutect2
- TMEM183B | n.417A>G | RNA (SNP) | VAF 131/388 reads (34%) | catalogued as rs767100902; called by muse, mutect2, varscan2
- TMEM214 | c.1152+66G>T | Intron (SNP) | VAF 150/565 reads (27%) | catalogued as COSV53192124; called by muse, mutect2, varscan2
- VRK3 | c.1218-1136C>T | Intron (SNP) | VAF 21/56 reads (38%) | called by muse, mutect2, varscan2
- ZNF655 | c.136+3194C>T | Intron (SNP) | VAF 201/362 reads (56%) | catalogued as rs776026660; called by muse, mutect2, varscan2
- ZNF90 | chr19:20121298 A>C | 3'Flank (SNP) | VAF 57/93 reads (61%) | called by muse, mutect2, varscan2
